Somatic mutation profile of tumor specimen ALCH-ADMM-TTP1-A (aliquot ALCH-ADMM-TTP1-A-1-0-D-A608-36) from ALCHEMIST case ALCH-ADMM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.3 years (27,152 days).
Specimen ALCH-ADMM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5cd598e-9612-4a05-a348-ba931425b24a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADMM-NB1-A (Blood Derived Normal), aliquot ALCH-ADMM-NB1-A-1-0-D-A587-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/571c7e24-8288-40be-8151-906a694a201d

The open-access MAF lists 874 somatic variants for this specimen: 609 protein-altering or splice-affecting, 162 silent, 103 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 531, Silent 162, Intron 48, Nonsense Mutation 33, RNA 19, Frame Shift Del 17, Splice Site 15, 3'UTR 12, 5'UTR 11, Splice Region 8, 5'Flank 7, 3'Flank 6.

Variants (750 of 874; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PJVK | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 167/647 reads (26%) | catalogued as rs118203989, CM072984; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 86/297 reads (29%) | catalogued as rs869312782, COSV52692559, COSV52721885, COSV53153630, COSV53758203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.128del p.P43Lfs*43 | Frame Shift Del (DEL) | VAF 108/424 reads (25%) | catalogued as COSV99257687; called by mutect2, pindel, varscan2
- ABCB1 | c.3547C>T p.R1183C | Missense Mutation (SNP) | VAF 72/553 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199676098, COSV55947916; called by muse, mutect2, varscan2
- ABCB10 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 39/449 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780008378; called by muse, mutect2
- ABCC1 | c.2645G>T p.G882V | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.194); catalogued as COSV60695851; called by muse, mutect2, varscan2
- ADAMTS7 | c.2626G>T p.E876* | Nonsense Mutation (SNP) | VAF 118/229 reads (52%) | catalogued as COSV101183053; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4604G>A p.G1535E | Missense Mutation (SNP) | VAF 75/371 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.062); catalogued as COSV54461873; called by muse, mutect2, varscan2
- ADGRA1 | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs764482205, COSV63416460, COSV63416660; called by muse, mutect2, varscan2
- ADGRA3 | c.3104G>T p.S1035I | Missense Mutation (SNP) | VAF 107/395 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV51569748; called by muse, mutect2, varscan2
- ADGRG4 | c.9206-1G>T p.X3069_splice | Splice Site (SNP) | VAF 69/200 reads (35%) | catalogued as COSV54955497; called by muse, mutect2, varscan2
- ADH1B | c.1045C>A p.H349N | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs750015759; called by muse, mutect2, varscan2
- AFF2 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 112/214 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557256437; called by muse, mutect2, varscan2
- AHNAK | c.17495G>A p.S5832N | Missense Mutation (SNP) | VAF 85/358 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs147392644; called by muse, mutect2, varscan2
- ANKEF1 | c.336T>A p.N112K | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.186); catalogued as rs761476237; called by muse, varscan2
- ARHGAP25 | c.342C>G p.I114M (on ENST00000409202 / NM_001007231.3; = p.I107M on NM_014882.3) | Missense Mutation (SNP) | VAF 83/305 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54907340; called by muse, mutect2, varscan2
- ARHGAP32 | c.3478G>A p.D1160N (on ENST00000310343 / NM_001378025.1; = p.D811N on NM_014715.4) | Missense Mutation (SNP) | VAF 105/813 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs776440785; called by muse, mutect2, varscan2
- ASTN2 | c.2894C>T p.S965L (on ENST00000313400 / NM_001365069.1; = p.S914L on NM_014010.5) | Missense Mutation (SNP) | VAF 28/664 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV56016044; called by muse, mutect2
- ASXL1 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 216/1068 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1263730148; called by muse, mutect2, varscan2
- BOC | c.2135C>A p.P712H | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56351278; called by muse, mutect2, varscan2
- C11orf1 | c.167G>C p.R56P | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99500255; called by muse, mutect2, varscan2
- C18orf54 | c.976-1G>T p.X326_splice | Splice Site (SNP) | VAF 23/111 reads (21%) | catalogued as COSV100266637, COSV55617672; called by muse, mutect2, varscan2
- CCDC74B | c.363C>A p.N121K | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs751548726, COSV60101680; called by muse, mutect2, varscan2
- CD22 | c.118G>T p.V40F | Missense Mutation (SNP) | VAF 101/352 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV50056700; called by muse, mutect2, varscan2
- CDKN2A | c.298G>C p.A100P | Missense Mutation (SNP) | VAF 186/605 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as CX024722, COSV58694515, COSV58704405, COSV58722643; called by muse, mutect2, varscan2
- CFAP70 | c.1355G>C p.S452T | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1297434783; called by muse, mutect2, varscan2
- CFHR5 | c.1663C>T p.R555* | Nonsense Mutation (SNP) | VAF 77/701 reads (11%) | catalogued as rs780410370, COSV56820683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD8 | c.3667A>G p.T1223A (on ENST00000646647 / NM_001170629.2; = p.T944A on NM_020920.4) | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67872355; called by muse, mutect2
- CHRM3 | c.1464A>T p.K488N | Missense Mutation (SNP) | VAF 118/1037 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55097271; called by muse, mutect2, varscan2
- CNTNAP2 | c.1402A>T p.N468Y | Missense Mutation (SNP) | VAF 72/564 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs1358247051, COSV62267203; called by muse, mutect2, varscan2
- COL11A1 | c.2772G>T p.Q924H | Missense Mutation (SNP) | VAF 187/649 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV62185933; called by muse, mutect2, varscan2
- COL5A2 | c.4441G>T p.D1481Y | Missense Mutation (SNP) | VAF 229/1047 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66407894; called by muse, mutect2, varscan2
- COL6A6 | c.2810G>T p.R937L | Missense Mutation (SNP) | VAF 144/378 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV62027261; called by muse, mutect2, varscan2
- COL6A6 | c.5393C>A p.A1798E | Missense Mutation (SNP) | VAF 102/480 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs554895053, COSV62027886; called by muse, varscan2
- COL9A3 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 17/329 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV100102532; called by muse, mutect2
- CPB1 | c.589T>C p.Y197H | Missense Mutation (SNP) | VAF 60/390 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1272704612; called by muse, mutect2
- CSMD3 | c.3005-1G>A p.X1002_splice (on ENST00000297405 / NM_001363185.1; = p.X898_splice on NM_052900.3) | Splice Site (SNP) | VAF 61/496 reads (12%) | catalogued as COSV52098395, COSV99820186; called by muse, mutect2, varscan2
- CUX2 | c.3855C>A p.S1285R | Missense Mutation (SNP) | VAF 67/289 reads (23%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1275625398; called by muse, mutect2, varscan2
- CXCL12 | c.282A>T p.*94Cext*11 | Nonstop Mutation (SNP) | VAF 46/437 reads (11%) | catalogued as COSV59109252; called by muse, mutect2, varscan2
- CYRIA | c.462C>A p.D154E | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100838312; called by muse, mutect2
- DCC | c.350G>T p.C117F | Missense Mutation (SNP) | VAF 161/761 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59128258; called by muse, mutect2, varscan2
- DECR1 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779204338; called by muse, mutect2, varscan2
- DENND1B | c.132A>G p.I44M | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs767327145; called by muse, mutect2, varscan2
- DMTF1 | c.374A>G p.E125G | Missense Mutation (SNP) | VAF 42/337 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs370553524; called by muse, mutect2, varscan2
- DMWD | c.1936del p.E646Kfs*13 | Frame Shift Del (DEL) | VAF 42/251 reads (17%) | catalogued as COSV52180205; called by mutect2, pindel, varscan2
- DNAH11 | c.3442G>T p.E1148* | Nonsense Mutation (SNP) | VAF 107/256 reads (42%) | catalogued as COSV60951598; called by muse, mutect2, varscan2
- DNAH3 | c.4286G>A p.G1429D | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770450578; called by muse, mutect2, varscan2
- DNAH7 | c.10246G>C p.D3416H | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100415707, COSV56775529; called by muse, mutect2, varscan2
- ECT2L | c.2333C>G p.S778* | Nonsense Mutation (SNP) | VAF 23/165 reads (14%) | catalogued as COSV62884873; called by muse, mutect2, varscan2
- ENPP2 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.992); catalogued as rs745478300, COSV99309485; called by muse, mutect2, varscan2
- EPHA2 | c.602G>C p.C201S | Missense Mutation (SNP) | VAF 64/638 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64454415; called by muse, mutect2
- ERCC4 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 63/501 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV100318761; called by muse, mutect2, varscan2
- ERN2 | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56832507; called by muse, mutect2, varscan2
- EXOC3 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 71/558 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV100155213; called by muse, mutect2, varscan2
- EXOC4 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54114676; called by muse, mutect2, varscan2
- FAM107B | c.28A>G p.K10E | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1203916205; called by muse, mutect2
- FAM131B | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 90/591 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100577625, COSV58367480; called by muse, mutect2, varscan2
- FAM135B | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50522898; called by muse, mutect2, varscan2
- FAT3 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 138/346 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs771773390, COSV53074488; called by muse, mutect2, varscan2
- FAT3 | c.13403C>A p.P4468H | Missense Mutation (SNP) | VAF 83/685 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99973508; called by muse, mutect2, varscan2
- FBL | c.832G>T p.V278L | Missense Mutation (SNP) | VAF 330/662 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV55681442; called by muse, mutect2, varscan2
- FBXL7 | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 55/526 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61645430; called by muse, mutect2
- FEZ2 | c.977A>G p.K326R | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs1278114986; called by muse, mutect2, varscan2
- FGFRL1 | c.1355C>G p.S452C | Missense Mutation (SNP) | VAF 149/416 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.428); catalogued as COSV53258588; called by muse, varscan2
- GJA1 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 255/889 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.479); catalogued as CM161897, COSV56996979; called by muse, mutect2, varscan2
- GLYATL3 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 134/447 reads (30%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.924); catalogued as COSV64592309; called by muse, mutect2, varscan2
- GPR32 | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.403); catalogued as rs1332702317; called by muse, mutect2
- GPR75 | c.616_619del p.L206Mfs*18 | Frame Shift Del (DEL) | VAF 100/546 reads (18%) | catalogued as rs763813086; called by mutect2, pindel, varscan2
- GRB10 | c.1203G>T p.M401I (on ENST00000398812; = p.M355I on NM_001001549.3) | Missense Mutation (SNP) | VAF 136/1510 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs562798543; called by muse, mutect2
- GRM8 | c.2570A>T p.K857M | Missense Mutation (SNP) | VAF 83/691 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100281640, COSV58822667; called by muse, mutect2, varscan2
- HCN1 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 64/519 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as COSV57537464; called by muse, mutect2, varscan2
- HCN2 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs781664647, COSV52116135; called by muse, mutect2, varscan2
- HJURP | c.1997G>T p.R666L | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100982636; called by muse, mutect2, varscan2
- HOXB2 | c.913C>G p.P305A | Missense Mutation (SNP) | VAF 98/397 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as rs1397558635; called by muse, mutect2, varscan2
- HSD11B1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 299/880 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54829522; called by muse, mutect2, varscan2
- HTR3C | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 96/305 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs761845667; called by muse, mutect2, varscan2
- IGHV3-33 | c.343T>C p.C115R | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1555493480; called by muse, varscan2
- IQCC | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 66/604 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs769081655; called by muse, mutect2, varscan2
- ITGBL1 | c.1195C>A p.Q399K | Missense Mutation (SNP) | VAF 27/314 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV101095302; called by muse, mutect2
- KCNH2 | c.2372G>T p.R791L | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100061541; called by muse, mutect2, varscan2
- KCNQ3 | c.2605A>T p.N869Y | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); catalogued as COSV66483267; called by muse, mutect2, varscan2
- KIF1A | c.4969C>A p.R1657S (on ENST00000320389 / NM_001379639.1; = p.R1649S on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/486 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57490522; called by muse, mutect2, varscan2
- KMT2D | c.8417G>T p.G2806V | Missense Mutation (SNP) | VAF 438/993 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV56485764; called by muse, mutect2, varscan2
- LILRB1 | c.860G>T p.G287V (on ENST00000427581; = p.G251V on NM_006669.6) | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767740163; called by muse, varscan2
- LINC02860 | n.891A>G | Splice Region (SNP) | VAF 27/292 reads (9%) | catalogued as rs185838548; called by muse, mutect2
- LRATD1 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 124/423 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99039157; called by muse, mutect2, varscan2
- LRFN5 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99984449; called by muse, mutect2, varscan2
- LRP12 | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52634862; called by muse, mutect2, varscan2
- LRP1B | c.4916G>T p.G1639V | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as rs143407457; called by muse, mutect2, varscan2
- LRRC66 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 61/524 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.095); catalogued as rs755573156, COSV58632802; called by muse, mutect2, varscan2
- LSAMP | c.93C>G p.S31R | Missense Mutation (SNP) | VAF 286/713 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV61301906; called by muse, mutect2, varscan2
- MAB21L3 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 132/1034 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as rs368748884; called by muse, varscan2
- MAGEA4 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 70/314 reads (22%) | catalogued as COSV52341313; called by muse, mutect2, varscan2
- MAGEB18 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100305459; called by muse, mutect2, varscan2
- MATK | c.418G>A p.E140K (on ENST00000310132 / NM_139355.3; = p.E141K on NM_002378.4) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs754573229, COSV59554132; called by muse, mutect2, varscan2
- MBOAT1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs775318866; called by muse, mutect2, varscan2
- MIDN | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 54/388 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as rs773701369, COSV56297460; called by muse, mutect2, varscan2
- MIGA1 | c.1106G>T p.R369I | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1305945142; called by muse, mutect2, varscan2
- MSX2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 57/474 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1201449653, COSV53327472; called by muse, mutect2, varscan2
- MYBPC1 | c.1631G>A p.R544H (on ENST00000550270 / NM_206820.2; = p.R569H on NM_002465.4) | Missense Mutation (SNP) | VAF 79/723 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149828249; called by muse, mutect2, varscan2
- MYBPC3 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs371711564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYBPH | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 119/263 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV99047772; called by muse, mutect2, varscan2
- MYH1 | c.2042A>G p.E681G | Missense Mutation (SNP) | VAF 62/403 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV99876710; called by muse, mutect2, varscan2
- MYOM2 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 50/466 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100036318; called by muse, mutect2, varscan2
- MYOM2 | c.4112A>T p.N1371I | Missense Mutation (SNP) | VAF 30/875 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs763876833; called by muse, mutect2
- NAALAD2 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 50/469 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs775425061, COSV58964937; called by muse, mutect2, varscan2
- NALCN | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.25); catalogued as rs551879819; called by muse, mutect2, varscan2
- NEK2 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 144/397 reads (36%) | catalogued as COSV65355689; called by muse, mutect2, varscan2
- NELL2 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 248/537 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV61570787; called by muse, mutect2, varscan2
- NOTCH1 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 24/482 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.904); catalogued as rs1182867386, COSV53079912; called by muse, mutect2
- NR4A3 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58245974; called by muse, mutect2, varscan2
- NRXN3 | c.3035G>C p.R1012P (on ENST00000335750 / NM_001330195.2; = p.R639P on NM_004796.6) | Missense Mutation (SNP) | VAF 53/425 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59750874; called by muse, mutect2, varscan2
- OR2AJ1 | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 73/624 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59089383; called by muse, mutect2, varscan2
- OR2L2 | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 185/489 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV63560714; called by muse, mutect2, varscan2
- OR2M2 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 60/439 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV62897905; called by muse, mutect2, varscan2
- OR4A5 | c.159G>T p.L53F | Missense Mutation (SNP) | VAF 93/409 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs1223486891; called by muse, varscan2
- OR4C6 | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 135/593 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.521); catalogued as rs776313625; called by muse, mutect2, varscan2
- OR51G2 | c.79C>A p.R27S | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs760244072; called by muse, mutect2, varscan2
- OR56A4 | c.510C>G p.F170L | Missense Mutation (SNP) | VAF 65/467 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.104); catalogued as COSV58109980; called by muse, mutect2, varscan2
- OR5F1 | c.59C>A p.T20K | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as COSV53545997; called by muse, mutect2
- OR6B2 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 61/355 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751434097; called by muse, mutect2, varscan2
- PAMR1 | c.1339G>A p.G447R (on ENST00000619888 / NM_001001991.3; = p.G464R on NM_015430.4) | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768832915; called by muse, mutect2
- PAX4 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 110/1110 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs767181337; called by muse, mutect2
- PCDH17 | c.1865G>C p.R622P | Missense Mutation (SNP) | VAF 120/299 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64980369; called by muse, mutect2, varscan2
- PCDHGA4 | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 82/575 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs1256895826; called by muse, mutect2, varscan2
- PDYN | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 138/420 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV54101877, COSV54103082; called by muse, mutect2, varscan2
- PIK3R1 | c.502+1G>T p.X168_splice | Splice Site (SNP) | VAF 56/353 reads (16%) | catalogued as rs773461483; called by muse, mutect2, varscan2
- PIP4K2C | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 264/619 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100724029; called by muse, mutect2, varscan2
- PLEKHM1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69599162; called by muse, mutect2
- PLG | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 54/501 reads (11%) | catalogued as COSV51981229; called by muse, mutect2, varscan2
- PNP | c.12A>G p.G4= | Splice Region (SNP) | VAF 71/536 reads (13%) | catalogued as COSV64092075, COSV64092453; called by muse, mutect2, varscan2
- PRF1 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1373180931; called by muse, mutect2, varscan2
- PTGER4 | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 718/1252 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56721065; called by muse, mutect2, varscan2
- PTPRT | c.1607C>G p.S536W | Missense Mutation (SNP) | VAF 205/579 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs192708116, COSV62005031; called by muse, mutect2, varscan2
- PYHIN1 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as COSV63732082; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2668C>T p.Q890* | Nonsense Mutation (SNP) | VAF 29/207 reads (14%) | catalogued as COSV54758467; called by muse, mutect2, varscan2
- RBM44 | c.839C>T p.S280F (on ENST00000611254; = p.S914F on NM_001080504.2) | Missense Mutation (SNP) | VAF 55/382 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.073); catalogued as rs758832412; called by muse, mutect2, varscan2
- RELN | c.9983G>C p.S3328T | Missense Mutation (SNP) | VAF 80/557 reads (14%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.932); catalogued as COSV59002692; called by muse, mutect2, varscan2
- RIMBP2 | c.1334G>T p.R445M | Missense Mutation (SNP) | VAF 152/663 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs775602620, COSV99898830; called by muse, mutect2, varscan2
- RPRD2 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 80/870 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1553897811; called by muse, mutect2
- SEC63 | c.1210-1G>C p.X404_splice | Splice Site (SNP) | VAF 52/192 reads (27%) | catalogued as COSV64602128; called by muse, mutect2, varscan2
- SEMA6C | c.2743G>T p.G915W | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.435); catalogued as rs780448271; called by muse, mutect2, varscan2
- SERPINB3 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV52189830; called by muse, mutect2, varscan2
- SHISA9 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.626); catalogued as COSV69632496; called by muse, mutect2, varscan2
- SLAMF1 | c.113A>T p.Q38L | Missense Mutation (SNP) | VAF 120/272 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV52498788; called by muse, varscan2
- SLC37A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 165/569 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1239265740; called by muse, mutect2, varscan2
- SLC39A4 | c.1436C>G p.P479R (on ENST00000301305 / NM_001374839.1; = p.P454R on NM_017767.3) | Missense Mutation (SNP) | VAF 82/515 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1554872457; called by muse, mutect2, varscan2
- SLC3A1 | c.1799G>C p.G600A | Missense Mutation (SNP) | VAF 66/551 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as CM013604; called by muse, mutect2, varscan2
- SMG5 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 105/252 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV62436560; called by muse, mutect2, varscan2
- SNX33 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 100/544 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs759856909, COSV57914259; called by muse, varscan2
- SOX30 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 60/444 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53936280; called by muse, mutect2, varscan2
- SPAG17 | c.6256G>T p.G2086* | Nonsense Mutation (SNP) | VAF 40/333 reads (12%) | catalogued as COSV60470711; called by muse, mutect2, varscan2
- SPAM1 | c.925A>C p.T309P | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56147840; called by mutect2, varscan2
- STK39 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 76/363 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100596508; called by muse, varscan2
- STPG2 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99759253; called by muse, mutect2, varscan2
- STYXL2 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 182/698 reads (26%) | catalogued as COSV54803011; called by muse, mutect2, varscan2
- SUSD6 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61367110; called by muse, mutect2, varscan2
- TAF1L | c.5349C>A p.D1783E | Missense Mutation (SNP) | VAF 173/635 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.99); catalogued as rs762034779; called by muse, mutect2, varscan2
- TAS1R2 | c.1864G>T p.V622L | Missense Mutation (SNP) | VAF 294/828 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); catalogued as rs968855809; called by muse, varscan2
- TECRL | c.964+1G>T p.X322_splice | Splice Site (SNP) | VAF 21/195 reads (11%) | catalogued as rs1165168888, COSV67089373; called by muse, mutect2, varscan2
- TICRR | c.1723A>G p.M575V | Missense Mutation (SNP) | VAF 107/454 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1030702542; called by muse, mutect2, varscan2
- TMEM151A | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.329); catalogued as rs1476731026; called by muse, mutect2, varscan2
- TMEM178A | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56143288; called by muse, mutect2, varscan2
- TMEM183A | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1348689691; called by muse, varscan2
- TMTC2 | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 76/381 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.63); catalogued as rs866355714; called by muse, mutect2, varscan2
- TPSD1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs772515452; called by muse, mutect2, varscan2
- TRPM3 | c.428C>A p.T143N (on ENST00000357533 / NM_001366142.2; = p.T112N on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/460 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs758502760; called by muse, mutect2, varscan2
- TTC38 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101123858; called by muse, mutect2, varscan2
- TTN | c.22919G>T p.G7640V (on ENST00000591111; = p.G6713V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/215 reads (26%) | PolyPhen probably damaging (0.99); catalogued as COSV100611627; called by muse, mutect2, varscan2
- TUT4 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as COSV57115379; called by muse, mutect2, varscan2
- TYR | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 79/645 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757724131; called by muse, mutect2, varscan2
- UGT2B4 | c.1366C>G p.P456A | Missense Mutation (SNP) | VAF 751/1219 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100522601; called by muse, mutect2
- UHMK1 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs868665454; called by muse, mutect2
- UNC13C | c.1516G>T p.D506Y | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs750642500, COSV52909371; called by muse, mutect2, varscan2
- USF1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs1385345803, COSV99231071; called by muse, mutect2
- USH2A | c.10676C>A p.P3559Q | Missense Mutation (SNP) | VAF 208/622 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1342031054; called by muse, mutect2, varscan2
- VEGFC | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV99710522; called by muse, mutect2
- VWF | c.5781C>A p.C1927* | Nonsense Mutation (SNP) | VAF 461/869 reads (53%) | catalogued as COSV99780366; called by muse, mutect2, varscan2
- WDR86 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as rs766177920, COSV57842963; called by muse, mutect2, varscan2
- WNT8B | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs1315541597, COSV59325389; called by muse, mutect2
- WWC1 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 196/483 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54650243; called by muse, mutect2, varscan2
- XRCC3 | c.898C>G p.R300G | Missense Mutation (SNP) | VAF 89/575 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754089796; called by muse, mutect2, varscan2
- ZEB2 | c.2947G>T p.D983Y | Missense Mutation (SNP) | VAF 189/729 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57956923; called by muse, mutect2, varscan2
- ZFHX4 | c.7594C>T p.P2532S | Missense Mutation (SNP) | VAF 70/458 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.344); catalogued as rs754088730; called by muse, mutect2, varscan2
- ZNF160 | c.1990C>G p.L664V | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs777341049; called by muse, mutect2, varscan2
- ZNF324B | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1315815414, COSV100351538; called by muse, mutect2, varscan2
- ZNF423 | c.1676C>A p.P559Q (on ENST00000563137 / NM_001379286.1; = p.P551Q on NM_015069.4) | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52196054; called by muse, mutect2, varscan2
- ZNF536 | c.2150C>A p.P717H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs750553160, COSV100835649, COSV62821184; called by muse, mutect2
- ZNF646 | c.2545C>G p.Q849E | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54923018; called by muse, mutect2, varscan2
- ZNF684 | c.982A>G p.S328G | Missense Mutation (SNP) | VAF 68/468 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1011370203, COSV65518942; called by muse, mutect2, varscan2
- ZNF804B | c.1503G>T p.L501F | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.483); catalogued as rs1481924564; called by muse, mutect2, varscan2
- ZNF91 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1254662779; called by muse, mutect2, varscan2
- ZW10 | c.136T>A p.Y46N | Missense Mutation (SNP) | VAF 44/368 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52315612; called by muse, mutect2, varscan2
- ABCA2 | c.2906G>A p.G969D (on ENST00000614293; = p.G939D on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, varscan2
- ABCA5 | c.3902A>T p.D1301V | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.062); called by muse, mutect2
- ABCG4 | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 116/254 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC073610.2 | c.433C>A p.Q145K | Missense Mutation (SNP) | VAF 90/770 reads (12%) | SIFT tolerated, low confidence (0.34); called by muse, mutect2, varscan2
- AC126283.2 | c.612G>T p.M204I | Missense Mutation (SNP) | VAF 168/457 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACO1 | c.876C>A p.D292E | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- ACOD1 | c.989C>G p.A330G | Missense Mutation (SNP) | VAF 119/677 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ADAM12 | c.2672C>A p.P891H | Missense Mutation (SNP) | VAF 48/349 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ADAMTS2 | c.815dup p.V274Rfs*3 | Frame Shift Ins (INS) | VAF 208/686 reads (30%) | called by pindel, varscan2
- ADAMTSL3 | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 201/695 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADCY2 | c.2919G>A p.M973I | Missense Mutation (SNP) | VAF 31/647 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2
- ADGRG7 | c.1109A>T p.K370M | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2
- ADGRL3 | c.393C>A p.D131E (on ENST00000506720 / NM_001322402.2; = p.D63E on NM_015236.6) | Missense Mutation (SNP) | VAF 54/462 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADRA2B | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by mutect2, varscan2
- AGO1 | c.2378G>T p.R793L | Missense Mutation (SNP) | VAF 112/1085 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- AGO4 | c.997G>T p.V333F | Missense Mutation (SNP) | VAF 111/275 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ALG1L | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 161/440 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ANKMY1 | c.2281G>C p.G761R | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD30A | c.3593A>G p.H1198R (on ENST00000611781; = p.H1142R on NM_052997.2) | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- ANO1 | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF2 | c.2368G>T p.A790S (on ENST00000361247 / NM_001162383.2; = p.A762S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARSL | c.16C>A p.H6N | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASB18 | c.1048C>A p.Q350K | Missense Mutation (SNP) | VAF 57/490 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- ATP2B2 | c.2239G>C p.E747Q (on ENST00000352432; = p.E713Q on NM_001683.5) | Missense Mutation (SNP) | VAF 64/677 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2
- ATXN2 | c.1084G>T p.V362L (on ENST00000550104; = p.V202L on NM_002973.4) | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AURKAIP1 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- B4GALNT4 | c.1366A>T p.R456W | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- BAZ2A | c.5656A>G p.M1886V | Missense Mutation (SNP) | VAF 66/940 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- BCAM | c.215C>A p.S72* | Nonsense Mutation (SNP) | VAF 38/236 reads (16%) | called by muse, mutect2, varscan2
- BDP1 | c.7808G>T p.G2603V | Missense Mutation (SNP) | VAF 91/330 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- BRI3 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- C3orf49 | c.377C>A p.P126H | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- C5 | c.4177G>T p.G1393C | Missense Mutation (SNP) | VAF 241/803 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- C5AR1 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- CA12 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 468/1055 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CABIN1 | c.3898G>T p.A1300S | Missense Mutation (SNP) | VAF 208/4514 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2
- CACNA1B | c.3807G>T p.K1269N | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CADM3 | c.520+1G>C p.X174_splice (on ENST00000368125 / NM_001127173.3; = p.X208_splice on NM_021189.5) | Splice Site (SNP) | VAF 58/558 reads (10%) | called by muse, mutect2, varscan2
- CAND2 | c.655C>G p.L219V (on ENST00000456430 / NM_001162499.2; = p.L126V on NM_012298.3) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAPNS1 | c.50del p.G17Efs*16 | Frame Shift Del (DEL) | VAF 35/196 reads (18%) | called by mutect2, pindel, varscan2
- CASP12 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 197/434 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAVIN1 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 55/872 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- CCDC166 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC28A | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC80 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 193/514 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- CCNB3 | c.1233G>T p.K411N | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CCT7 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 92/778 reads (12%) | called by muse, mutect2, varscan2
- CD1E | c.874C>A p.L292I | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CDC27 | c.1645G>T p.D549Y | Missense Mutation (SNP) | VAF 67/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CDH2 | c.2373G>T p.Q791H | Missense Mutation (SNP) | VAF 69/421 reads (16%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP250 | c.6064C>T p.Q2022* | Nonsense Mutation (SNP) | VAF 64/276 reads (23%) | called by muse, mutect2, varscan2
- CEP290 | c.5797G>A p.E1933K | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CFAP46 | c.5952G>T p.S1984= | Splice Region (SNP) | VAF 47/305 reads (15%) | called by muse, mutect2, varscan2
- CFH | c.2257T>A p.C753S | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHL1 | c.3330G>T p.K1110N (on ENST00000397491 / NM_001253387.1; = p.K1126N on NM_006614.4) | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRFAM7A | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 74/540 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- CHRM2 | c.265T>C p.W89R | Missense Mutation (SNP) | VAF 243/1290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIBAR2 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CLDN1 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 233/936 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLEC18B | c.6del p.H3Ifs*41 | Frame Shift Del (DEL) | VAF 71/626 reads (11%) | called by mutect2, pindel, varscan2
- CLEC1B | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 353/709 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CLEC3A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 95/280 reads (34%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLSTN2 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CMYA5 | c.3478G>C p.V1160L | Missense Mutation (SNP) | VAF 105/431 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CNKSR2 | c.1045C>G p.Q349E | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CNTN5 | c.1410T>A p.S470R | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- COL13A1 | c.608C>A p.P203H (on ENST00000398978 / NM_001130103.2; = p.P165H on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/424 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL5A2 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 190/822 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPS1 | c.4499C>T p.A1500V | Missense Mutation (SNP) | VAF 144/619 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRACDL | c.2114G>T p.G705V | Missense Mutation (SNP) | VAF 89/414 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CRK | c.768_772del p.L256Ffs*5 | Frame Shift Del (DEL) | VAF 37/103 reads (36%) | called by mutect2, pindel, varscan2
- CSAG3 | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 93/597 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSMD3 | c.6248C>A p.S2083Y (on ENST00000297405 / NM_001363185.1; = p.S1979Y on NM_052900.3) | Missense Mutation (SNP) | VAF 142/544 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CSMD3 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CSN2 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 35/718 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.114); called by muse, mutect2
- CSTF2T | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 68/532 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUX2 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2
- CYP39A1 | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 89/293 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DCAF13 | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2
- DCAF4L2 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 66/604 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DDX52 | c.1497G>T p.R499S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DGKQ | c.2290G>C p.E764Q | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- DHRS4L2 | c.458T>G p.V153G | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIP2C | c.3409C>G p.L1137V | Missense Mutation (SNP) | VAF 66/543 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DISC1 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 130/710 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- DISP3 | c.1889G>A p.S630N | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, varscan2
- DLEC1 | c.1807A>T p.S603C | Missense Mutation (SNP) | VAF 47/391 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DLGAP2 | c.2197T>A p.S733T | Missense Mutation (SNP) | VAF 85/407 reads (21%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DLGAP3 | c.833G>T p.R278M | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- DMRTC2 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DNAH3 | c.3191C>T p.A1064V | Missense Mutation (SNP) | VAF 46/375 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DNM3 | c.1980G>T p.E660D (on ENST00000355305 / NM_001350206.2; = p.E654D on NM_015569.5) | Missense Mutation (SNP) | VAF 85/595 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- DOT1L | c.265-1G>A p.X89_splice | Splice Site (SNP) | VAF 53/120 reads (44%) | called by muse, varscan2
- DRD1 | c.1155C>A p.C385* | Nonsense Mutation (SNP) | VAF 69/230 reads (30%) | called by muse, mutect2, varscan2
- DSPP | c.254_255insA p.W85* | Nonsense Mutation (INS) | VAF 110/509 reads (22%) | called by mutect2, pindel, varscan2
- DVL3 | c.760A>G p.M254V | Missense Mutation (SNP) | VAF 112/448 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- DYDC1 | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- EBF2 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 36/579 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EBF4 | c.528G>C p.E176D (on ENST00000609451; = p.E172D on NM_001110514.1) | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2
- ECD | c.384G>T p.W128C | Missense Mutation (SNP) | VAF 45/327 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDNRB | c.541C>A p.Q181K (on ENST00000377211 / NM_001201397.1; = p.Q91K on NM_000115.5) | Missense Mutation (SNP) | VAF 104/285 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EME1 | c.1361A>G p.E454G | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2
- EPHB6 | c.2440del p.R814Vfs*42 | Frame Shift Del (DEL) | VAF 30/280 reads (11%) | called by pindel, varscan2
- EXO1 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 320/966 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC5 | c.2078A>G p.Q693R | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EXOC7 | c.1628G>T p.R543L (on ENST00000335146 / NM_001145297.4; = p.R461L on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/487 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- EXPH5 | c.4904G>A p.G1635D | Missense Mutation (SNP) | VAF 108/297 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- EYS | c.1619G>T p.S540I | Missense Mutation (SNP) | VAF 120/416 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FAAH2 | c.1523A>T p.N508I | Missense Mutation (SNP) | VAF 94/269 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FAT3 | c.7476C>A p.Y2492* | Nonsense Mutation (SNP) | VAF 188/454 reads (41%) | called by muse, mutect2, varscan2
- FBXO7 | c.1307G>T p.S436I | Missense Mutation (SNP) | VAF 147/391 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FGB | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 103/680 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FGF19 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- FKBP6 | c.857A>G p.N286S | Missense Mutation (SNP) | VAF 201/808 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- FLG | c.10865C>G p.A3622G | Missense Mutation (SNP) | VAF 346/1444 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- FMNL2 | c.362G>C p.W121S | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FMNL2 | c.1512G>T p.M504I | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMO1 | c.765G>T p.L255F | Missense Mutation (SNP) | VAF 245/1135 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- FNDC1 | c.5380A>T p.K1794* | Nonsense Mutation (SNP) | VAF 143/562 reads (25%) | called by muse, mutect2, varscan2
- FOLH1 | c.1736T>C p.V579A | Missense Mutation (SNP) | VAF 46/846 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.267); called by muse, mutect2
- FOXE3 | c.521C>A p.A174E | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FRAS1 | c.8348G>T p.G2783V | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FRAS1 | c.11328G>C p.K3776N | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- FRMD1 | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FRMPD1 | c.3143C>A p.P1048H | Missense Mutation (SNP) | VAF 101/322 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.10256C>A p.P3419Q | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD5 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- GABPB2 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- GABRB2 | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRR2 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 93/373 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRR3 | c.692T>A p.L231H | Missense Mutation (SNP) | VAF 70/649 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAD2 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- GAD2 | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 56/441 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT17 | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 38/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GCNT3 | c.816del p.R273Efs*6 | Frame Shift Del (DEL) | VAF 145/346 reads (42%) | called by mutect2, pindel, varscan2
- GDPD4 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GFRA3 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 57/472 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOT1L1 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- GP2 | c.61T>A p.C21S | Missense Mutation (SNP) | VAF 94/554 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- GPN2 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GPR32 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- GTSF1L | c.391A>T p.T131S | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GUCY2C | c.2230A>G p.T744A | Missense Mutation (SNP) | VAF 117/397 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- H2AC13 | c.119A>C p.Y40S | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- H2BW2 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HAUS7 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- HHLA1 | c.661T>A p.L221M | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLF | c.688del p.A230Qfs*19 | Frame Shift Del (DEL) | VAF 36/294 reads (12%) | called by mutect2, pindel, varscan2
- HMCN2 | c.14139T>A p.D4713E | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXB8 | c.497T>A p.L166Q | Missense Mutation (SNP) | VAF 84/387 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- HOXC9 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.1); called by muse, mutect2
- HR | c.2510C>A p.P837H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- HSD17B14 | c.492G>T p.M164I | Missense Mutation (SNP) | VAF 86/401 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- HSPG2 | c.11782A>T p.T3928S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by mutect2, varscan2
- HTR1F | c.79T>C p.S27P | Missense Mutation (SNP) | VAF 45/524 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- IGKV1D-43 | c.54A>C p.P18= | Splice Region (SNP) | VAF 96/463 reads (21%) | called by muse, mutect2, varscan2
- IGKV2D-26 | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 188/789 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGLV11-55 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 63/1476 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2
- IL20RA | c.1081G>T p.G361W | Missense Mutation (SNP) | VAF 143/450 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IMPDH1 | c.816G>C p.L272F (on ENST00000470772 / NM_001142573.2; = p.L358F on NM_000883.4) | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IREB2 | c.1381A>G p.K461E | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- IRX1 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 344/636 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ISL1 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 191/548 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- ITGA5 | c.2900C>T p.P967L | Missense Mutation (SNP) | VAF 58/666 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JPH2 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- KANSL1 | c.2407A>G p.T803A | Missense Mutation (SNP) | VAF 35/375 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- KCNB2 | c.1681C>A p.Q561K | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- KCNB2 | c.2050C>A p.Q684K | Missense Mutation (SNP) | VAF 74/460 reads (16%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNC2 | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 30/397 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KCND2 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 92/640 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KCNJ16 | c.18C>A p.S6R | Missense Mutation (SNP) | VAF 113/518 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- KDM5D | c.2573G>T p.G858V | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- KDR | c.3233T>G p.F1078C | Missense Mutation (SNP) | VAF 162/640 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF1A | c.5008C>T p.H1670Y (on ENST00000320389 / NM_001379639.1; = p.H1662Y on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/516 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- KIF1A | c.3383C>A p.P1128H | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KIF4A | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR3DL1 | c.742A>T p.S248C | Missense Mutation (SNP) | VAF 176/598 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- KLHL12 | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL26 | c.431A>T p.Q144L | Missense Mutation (SNP) | VAF 120/303 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLK13 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 99/401 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KMT2B | c.7636G>A p.E2546K | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LAIR1 | c.35-2A>T p.X12_splice | Splice Site (SNP) | VAF 135/453 reads (30%) | called by muse, mutect2, varscan2
- LAMB1 | c.4165G>C p.D1389H | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2
- LAMP5 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LINC02860 | n.890C>A | Splice Region (SNP) | VAF 26/288 reads (9%) | called by muse, mutect2
- LMOD1 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 203/525 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- LNPEP | c.3045G>C p.E1015D | Missense Mutation (SNP) | VAF 179/586 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, varscan2
- LRBA | c.5611G>T p.G1871C | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LRIT2 | c.720G>C p.Q240H | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP1B | c.13416-2A>T p.X4472_splice | Splice Site (SNP) | VAF 24/118 reads (20%) | called by muse, varscan2
- LRRC6 | c.143T>G p.I48S | Missense Mutation (SNP) | VAF 24/277 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRC66 | c.1235A>G p.K412R | Missense Mutation (SNP) | VAF 63/334 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LRRC69 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LSP1 | c.664T>A p.L222M | Missense Mutation (SNP) | VAF 96/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LYPD4 | c.645C>A p.N215K | Missense Mutation (SNP) | VAF 122/709 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- LZTFL1 | c.499A>T p.R167W | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MC5R | c.445C>A p.R149S | Missense Mutation (SNP) | VAF 60/431 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MEIOC | c.1822T>A p.F608I | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- MMP16 | c.1409A>T p.D470V | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MORF4L1 | c.939G>T p.L313F (on ENST00000331268 / NM_206839.2; = p.L274F on NM_006791.4) | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MPDZ | c.1656G>T p.V552= | Splice Region (SNP) | VAF 40/121 reads (33%) | called by muse, mutect2, varscan2
- MPHOSPH9 | c.2547G>T p.Q849H | Missense Mutation (SNP) | VAF 70/470 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MROH1 | c.4235G>C p.G1412A | Missense Mutation (SNP) | VAF 44/493 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- MTA2 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MTMR6 | c.1285A>G p.I429V | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC12 | c.15080G>T p.S5027I (on ENST00000379442; = p.S4884I on NM_001164462.1) | Missense Mutation (SNP) | VAF 56/394 reads (14%) | SIFT tolerated (0.16); called by muse, mutect2, varscan2
- MUC16 | c.32318A>G p.E10773G | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.29665A>C p.T9889P | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUC16 | c.4126C>A p.L1376I | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MX2 | c.39A>T p.R13S | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MXRA5 | c.3812C>A p.P1271H | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- MYH1 | c.2935G>T p.V979L | Missense Mutation (SNP) | VAF 123/857 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MYH13 | c.3365T>A p.L1122Q | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- MYO6 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 184/587 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYOM3 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV3 | c.4561G>A p.A1521T | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NAV3 | c.6033C>A p.N2011K (on ENST00000397909 / NM_001024383.2; = p.N1989K on NM_014903.6) | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2
- NBPF20 | c.137A>T p.Q46L | Missense Mutation (SNP) | VAF 178/1519 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.465); called by muse, mutect2
- NCKAP1L | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 157/363 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEB | c.17201T>A p.L5734Q | Missense Mutation (SNP) | VAF 113/528 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEBL | c.2347-1G>T p.X783_splice | Splice Site (SNP) | VAF 97/686 reads (14%) | called by mutect2, varscan2
- NFASC | c.2990C>A p.T997N | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- NLGN4Y | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 223/678 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- NLRP9 | c.1188T>A p.C396* | Nonsense Mutation (SNP) | VAF 56/433 reads (13%) | called by muse, mutect2, varscan2
- NOA1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 78/639 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- NOBOX | c.1334C>G p.P445R | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOS1 | c.3869A>T p.Q1290L | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- NPY5R | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 118/337 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- NR1H4 | c.425A>G p.D142G (on ENST00000551379 / NM_001206993.2; = p.D132G on NM_005123.4) | Missense Mutation (SNP) | VAF 78/557 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN1 | c.1204del p.Q402Kfs*47 | Frame Shift Del (DEL) | VAF 44/245 reads (18%) | called by mutect2, pindel, varscan2
- NUP188 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OCA2 | c.2307G>T p.M769I | Missense Mutation (SNP) | VAF 333/829 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ODC1 | c.1222G>A p.V408M | Missense Mutation (SNP) | VAF 90/566 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- OR10K2 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 50/430 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- OR11H2 | c.662C>A p.S221Y (on ENST00000556246; = p.S232Y on NM_001197287.1) | Missense Mutation (SNP) | VAF 106/913 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- OR2F2 | c.600G>C p.M200I | Missense Mutation (SNP) | VAF 75/528 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR2F2 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 77/529 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- OR2T11 | c.861C>A p.Y287* | Nonsense Mutation (SNP) | VAF 236/643 reads (37%) | called by muse, mutect2, varscan2
- OR4B1 | c.781T>G p.S261A | Missense Mutation (SNP) | VAF 47/385 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR4F4 | c.860T>C p.M287T | Missense Mutation (SNP) | VAF 300/1302 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- OR4K14 | c.411G>T p.M137I | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- OR4M1 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 94/816 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51C1P | c.858G>T p.L286F | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, varscan2
- OR52N4 | c.262T>C p.W88R | Missense Mutation (SNP) | VAF 166/452 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR5M8 | c.882A>T p.K294N | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- OR8B4 | c.773A>T p.Y258F | Missense Mutation (SNP) | VAF 60/502 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); called by muse, varscan2
- OR8K3 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OTOG | c.8087T>C p.M2696T | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- P2RY8 | c.106G>T p.V36F | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PADI6 | c.1717C>A p.L573M | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PAPPA2 | c.353T>A p.L118Q | Missense Mutation (SNP) | VAF 70/525 reads (13%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PAPSS1 | c.1072A>T p.T358S | Missense Mutation (SNP) | VAF 167/510 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PARP8 | c.130G>T p.V44F | Missense Mutation (SNP) | VAF 54/450 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PAX8 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 51/528 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2
- PCCA | c.1610A>G p.Q537R | Missense Mutation (SNP) | VAF 195/565 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PCDH15 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 103/892 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH7 | c.2319del p.D774Tfs*47 | Frame Shift Del (DEL) | VAF 168/633 reads (27%) | called by mutect2, pindel, varscan2
- PCDHA12 | c.2279C>A p.S760Y | Missense Mutation (SNP) | VAF 149/349 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PCDHA8 | c.2276G>T p.C759F | Missense Mutation (SNP) | VAF 154/384 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PCSK1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 148/686 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE11A | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 344/1383 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PDLIM3 | c.379T>A p.C127S (on ENST00000284770 / NM_001257963.1; = p.C294S on NM_014476.6) | Missense Mutation (SNP) | VAF 103/702 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PDZRN3 | c.2822G>T p.R941L | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- PEG3 | c.2784T>G p.N928K | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PIK3CB | c.1963G>C p.A655P | Missense Mutation (SNP) | VAF 21/431 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2
- PITPNA | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 66/435 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2R1 | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 49/359 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLEKHA4 | c.706del p.L236Sfs*8 | Frame Shift Del (DEL) | VAF 18/167 reads (11%) | called by mutect2, pindel, varscan2
- PMVK | c.402G>T p.L134F | Missense Mutation (SNP) | VAF 101/279 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PODN | c.395G>T p.G132V (on ENST00000395871; = p.G84V on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/590 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POTEC | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 115/1121 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- POU3F4 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- PPARGC1B | c.140T>A p.L47Q | Missense Mutation (SNP) | VAF 85/348 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPFIA1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 107/1352 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.017); called by muse, mutect2
- PPP1R2 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 115/329 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PPP2CA | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 128/362 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PRKDC | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.68); called by muse, mutect2
- PSD | c.1736A>G p.H579R | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- PTPRB | c.3836T>C p.I1279T | Missense Mutation (SNP) | VAF 54/656 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2
- PTPRC | c.2297G>A p.W766* | Nonsense Mutation (SNP) | VAF 205/875 reads (23%) | called by muse, mutect2, varscan2
- PTPRH | c.2496C>A p.H832Q | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PTPRZ1 | c.4386C>A p.H1462Q | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- R3HDM1 | c.1862G>T p.G621V | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- RAB11FIP4 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 64/230 reads (28%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.2934G>C p.K978N | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- RBM10 | c.2152A>T p.S718C | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- RELN | c.569del p.P190Hfs*3 | Frame Shift Del (DEL) | VAF 107/504 reads (21%) | called by mutect2, pindel, varscan2
- RFX4 | c.1092C>A p.Y364* (on ENST00000392842 / NM_213594.3; = p.Y270* on NM_032491.6) | Nonsense Mutation (SNP) | VAF 40/290 reads (14%) | called by muse, mutect2, varscan2
- RFX6 | c.2578T>G p.S860A | Missense Mutation (SNP) | VAF 187/549 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RGL4 | c.1270G>T p.V424F | Missense Mutation (SNP) | VAF 36/1088 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2
- RMND5A | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 61/342 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO1 | c.2144G>C p.G715A | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RP1 | c.1026G>T p.W342C | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPL15 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- RRP9 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- RTL9 | c.2663C>A p.P888Q | Missense Mutation (SNP) | VAF 75/448 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- RUNX3 | c.1022A>G p.Y341C | Missense Mutation (SNP) | VAF 37/402 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RYR2 | c.2150G>T p.G717V | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RYR2 | c.10198G>C p.A3400P | Missense Mutation (SNP) | VAF 31/335 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- SAMHD1 | c.496_509+6del p.X166_splice | Splice Site (DEL) | VAF 73/653 reads (11%) | called by mutect2, pindel
- SBSN | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 100/378 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, varscan2
- SCARF2 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 46/627 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN8A | c.3986A>T p.N1329I | Missense Mutation (SNP) | VAF 74/1750 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCRIB | c.3714+2T>A p.X1238_splice | Splice Site (SNP) | VAF 19/204 reads (9%) | called by muse, mutect2
- SCRIB | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SEMA3A | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 48/366 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SEMA5B | c.2020G>T p.A674S | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- SENP1 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 79/159 reads (50%) | called by muse, mutect2, varscan2
- SETD1B | c.1906G>A p.G636S | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3B3 | c.1288G>T p.G430* | Nonsense Mutation (SNP) | VAF 85/312 reads (27%) | called by muse, mutect2, varscan2
- SHC4 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 179/424 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SHCBP1L | c.947A>T p.E316V | Missense Mutation (SNP) | VAF 65/580 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SHCBP1L | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM3 | c.1040G>A p.W347* | Nonsense Mutation (SNP) | VAF 65/229 reads (28%) | called by muse, mutect2, varscan2
- SIGLEC11 | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC18A2 | c.-13G>T | Splice Region (SNP) | VAF 73/254 reads (29%) | called by muse, mutect2, varscan2
- SLC22A15 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 104/328 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- SLC30A10 | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 48/602 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2
- SLC39A10 | c.47_80del p.T16Kfs*17 | Frame Shift Del (DEL) | VAF 30/313 reads (10%) | called by mutect2, pindel
- SLC4A8 | c.1858T>A p.Y620N | Missense Mutation (SNP) | VAF 38/351 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.853); called by muse, varscan2
- SLC7A14 | c.938A>T p.Y313F | Missense Mutation (SNP) | VAF 238/1372 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SLC8A1 | c.1834G>T p.D612Y | Missense Mutation (SNP) | VAF 65/474 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC8A3 | c.1408G>T p.D470Y | Missense Mutation (SNP) | VAF 65/397 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO1C1 | c.1415T>C p.L472P | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2
- SNTG1 | c.410C>A p.S137* | Nonsense Mutation (SNP) | VAF 62/276 reads (22%) | called by muse, mutect2, varscan2
- SORCS3 | c.3191A>G p.K1064R | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SOX30 | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 49/522 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2
- SPANXN4 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- SPATA31A1 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 78/523 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by mutect2, varscan2
- SPATA31A6 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 280/1084 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SPICE1 | c.1155+1G>T p.X385_splice | Splice Site (SNP) | VAF 34/319 reads (11%) | called by muse, varscan2
- SPINT2 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 109/808 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPRED2 | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- SPRY4 | c.683G>T p.R228L (on ENST00000434127 / NM_001127496.3; = p.R251L on NM_030964.4) | Missense Mutation (SNP) | VAF 119/258 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SPTA1 | c.3608G>T p.C1203F | Missense Mutation (SNP) | VAF 414/1165 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SSH2 | c.3550G>T p.A1184S | Missense Mutation (SNP) | VAF 155/675 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- STRADB | c.1257G>C p.*419Yext*32 | Nonstop Mutation (SNP) | VAF 40/268 reads (15%) | called by muse, mutect2, varscan2
- STYXL2 | c.2864C>A p.S955Y | Missense Mutation (SNP) | VAF 209/489 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SVIL | c.1255G>T p.V419F | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SYNE1 | c.13684G>T p.V4562F (on ENST00000367255 / NM_182961.4; = p.V4491F on NM_033071.3) | Missense Mutation (SNP) | VAF 86/757 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- SYNE1 | c.438G>T p.Q146H (on ENST00000367255 / NM_182961.4; = p.Q153H on NM_033071.3) | Missense Mutation (SNP) | VAF 117/871 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNE2 | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 91/623 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SYNE3 | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- SYNRG | c.103A>T p.I35L | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TANC2 | c.5353T>C p.S1785P | Missense Mutation (SNP) | VAF 93/425 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TARDBP | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 261/786 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TCHH | c.643C>A p.L215M | Missense Mutation (SNP) | VAF 53/500 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- TENM3 | c.3049G>C p.V1017L | Missense Mutation (SNP) | VAF 122/493 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TENM4 | c.7536G>T p.E2512D | Missense Mutation (SNP) | VAF 197/476 reads (41%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- THRB | c.481T>C p.C161R | Missense Mutation (SNP) | VAF 79/648 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM71 | c.373A>T p.T125S (on ENST00000523829 / NM_001382398.1; = p.T106S on NM_144649.3) | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.194); called by muse, mutect2
- TP53BP1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 178/464 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- TP63 | c.158A>T p.E53V | Missense Mutation (SNP) | VAF 300/636 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- TP73 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAV20 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 88/513 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRHDE | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 168/413 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRIM4 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 50/428 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM64B | c.1203G>C p.R401S | Missense Mutation (SNP) | VAF 110/2084 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRIM64C | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 126/642 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.144); called by muse, varscan2
- TSC22D1 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 73/460 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSNARE1 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TSPAN10 | c.977G>T p.R326L (on ENST00000574882 / NM_001290212.1; = p.R288L on NM_031945.4) | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TTC6 | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.90479C>G p.A30160G (on ENST00000591111; = p.A22736G on NM_003319.4) | Missense Mutation (SNP) | VAF 36/200 reads (18%) | PolyPhen probably damaging (0.996); called by muse, mutect2
- TTN | c.83933C>A p.P27978Q (on ENST00000591111; = p.P20554Q on NM_003319.4) | Missense Mutation (SNP) | VAF 180/795 reads (23%) | PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- TTN | c.76441T>G p.L25481V (on ENST00000591111; = p.L18057V on NM_003319.4) | Missense Mutation (SNP) | VAF 27/228 reads (12%) | PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTN | c.22918G>T p.G7640* (on ENST00000591111; = p.G6713* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/217 reads (26%) | called by muse, mutect2, varscan2
- UBASH3B | c.62A>T p.K21I | Missense Mutation (SNP) | VAF 40/443 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- UBASH3B | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 236/570 reads (41%) | called by muse, mutect2, varscan2
- UBN1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 86/557 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- UBN2 | c.3278G>T p.S1093I | Missense Mutation (SNP) | VAF 84/736 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- UBXN2A | c.554G>T p.R185M | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- UBXN7 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 142/325 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- UGT1A9 | c.798G>T p.M266I | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UGT2B7 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 30/884 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); called by muse, mutect2
- UHMK1 | c.195_222del p.A66Kfs*16 | Frame Shift Del (DEL) | VAF 26/282 reads (9%) | called by mutect2, pindel
- UHRF1 | c.2319G>T p.Q773H (on ENST00000612630 / NM_001290050.1; = p.Q786H on NM_013282.4) | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.308); called by mutect2, varscan2
- UNC80 | c.4533G>T p.R1511S | Missense Mutation (SNP) | VAF 102/795 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- URB2 | c.592A>T p.T198S | Missense Mutation (SNP) | VAF 50/486 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); called by muse, mutect2
- USH2A | c.10675C>A p.P3559T | Missense Mutation (SNP) | VAF 207/623 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- USP19 | c.3206G>T p.R1069L | Missense Mutation (SNP) | VAF 69/341 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- UTF1 | c.803del p.P268Lfs*8 | Frame Shift Del (DEL) | VAF 23/126 reads (18%) | called by mutect2, pindel, varscan2
- VAT1L | c.425C>G p.P142R | Missense Mutation (SNP) | VAF 92/763 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- VPS13B | c.6898G>T p.D2300Y | Missense Mutation (SNP) | VAF 81/596 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WASHC2A | c.3830C>A p.P1277Q | Missense Mutation (SNP) | VAF 48/412 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- WBP1L | c.877G>T p.G293C | Missense Mutation (SNP) | VAF 125/467 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- WDFY4 | c.1042A>T p.T348S | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDFY4 | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 47/436 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- WDR49 | c.754A>T p.T252S (on ENST00000308378 / NM_001366158.1; = p.T593S on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, varscan2
- WSCD2 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- WWC3 | c.961G>C p.G321R | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XDH | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 258/982 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ZBED1 | c.1583C>A p.P528H | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZC3H14 | c.1280-2A>G p.X427_splice | Splice Site (SNP) | VAF 114/539 reads (21%) | called by muse, mutect2, varscan2
- ZCCHC12 | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 104/514 reads (20%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDBF2 | c.5774G>A p.R1925K | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC11B | c.222G>T p.V74= | Splice Region (SNP) | VAF 201/317 reads (63%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); called by muse, mutect2
- ZFHX2 | c.5128G>C p.E1710Q | Missense Mutation (SNP) | VAF 73/353 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- ZFPM2 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 94/322 reads (29%) | called by muse, mutect2, varscan2
- ZFYVE1 | c.1760C>G p.T587R | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZIC3 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, varscan2
- ZNF155 | c.1535C>G p.S512C | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZNF165 | c.383A>G p.E128G | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- ZNF229 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZNF318 | c.709A>T p.S237C | Missense Mutation (SNP) | VAF 108/700 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZNF404 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF418 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZNF451 | c.2944C>T p.Q982* (on ENST00000370706 / NM_001031623.3; = p.Q934* on NM_015555.2) | Nonsense Mutation (SNP) | VAF 138/642 reads (21%) | called by muse, mutect2, varscan2
- ZNF454 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 110/254 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ZNF469 | c.8378T>C p.L2793P (on ENST00000437464; = p.L2821P on NM_001367624.2) | Missense Mutation (SNP) | VAF 68/569 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF479 | c.240T>A p.N80K | Missense Mutation (SNP) | VAF 35/464 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2
- ZNF518B | c.2880del p.M960Ifs*3 | Frame Shift Del (DEL) | VAF 68/226 reads (30%) | called by mutect2, pindel, varscan2
- ZNF536 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF544 | c.1806G>T p.K602N | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- ZNF729 | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 60/354 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCC5 | c.2028G>A p.T676= | Silent (SNP) | VAF 63/383 reads (16%) | catalogued as rs758835113, COSV55591505; called by muse, mutect2, varscan2
- AFAP1L1 | c.1704G>A p.E568= | Silent (SNP) | VAF 36/219 reads (16%) | catalogued as COSV99695894; called by muse, mutect2, varscan2
- AIFM3 | c.450T>C p.S150= | Silent (SNP) | VAF 58/711 reads (8%) | called by muse, mutect2
- ALAS2 | c.1362C>G p.V454= | Silent (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- ANHX | c.1059G>A p.Q353= | Silent (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- AP2A1 | c.2631G>A p.Q877= | Silent (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- APBA1 | c.327G>T p.A109= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV99596352; called by muse, mutect2, varscan2
- ASCC3 | c.3672A>T p.V1224= | Silent (SNP) | VAF 51/334 reads (15%) | called by muse, mutect2, varscan2
- ASIC4 | c.1470C>A p.G490= (on ENST00000347842 / NM_182847.3; = p.G509= on NM_018674.6) | Silent (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- ATG9B | c.1536C>T p.A512= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1431569164; called by muse, mutect2, varscan2
- ATM | c.726T>G p.T242= | Silent (SNP) | VAF 84/868 reads (10%) | called by muse, mutect2
- BOC | c.2136C>T p.P712= | Silent (SNP) | VAF 28/276 reads (10%) | catalogued as rs147219655; called by muse, mutect2, varscan2
- C4orf54 | c.2373C>A p.S791= | Silent (SNP) | VAF 47/146 reads (32%) | called by muse, mutect2, varscan2
- C6orf120 | c.535T>C p.L179= | Silent (SNP) | VAF 40/277 reads (14%) | called by muse, mutect2
- C7 | c.966A>G p.E322= | Silent (SNP) | VAF 42/454 reads (9%) | catalogued as COSV57473583; called by muse, mutect2
- CD226 | c.471G>T p.T157= | Silent (SNP) | VAF 81/522 reads (16%) | catalogued as COSV99711050; called by muse, mutect2, varscan2
- CDH12 | c.2319C>A p.P773= | Silent (SNP) | VAF 58/822 reads (7%) | catalogued as COSV66421586; called by muse, mutect2
- CDK5RAP1 | c.831G>T p.R277= | Silent (SNP) | VAF 27/270 reads (10%) | called by muse, mutect2, varscan2
- CDKL2 | c.702G>C p.V234= | Silent (SNP) | VAF 18/374 reads (5%) | called by muse, mutect2
- CEP152 | c.3060A>G p.L1020= | Silent (SNP) | VAF 147/372 reads (40%) | catalogued as rs773681807; called by muse, mutect2, varscan2
- CFAP46 | c.3648G>A p.Q1216= | Silent (SNP) | VAF 26/185 reads (14%) | called by muse, mutect2, varscan2
- CFAP47 | c.1290A>T p.S430= | Silent (SNP) | VAF 69/238 reads (29%) | called by muse, mutect2, varscan2
- CHST2 | c.1398C>T p.S466= | Silent (SNP) | VAF 59/291 reads (20%) | called by muse, mutect2, varscan2
- CLCN1 | c.1710C>A p.A570= | Silent (SNP) | VAF 122/755 reads (16%) | called by muse, mutect2, varscan2
- CPO | c.537G>C p.G179= | Silent (SNP) | VAF 41/444 reads (9%) | called by muse, mutect2
- CXorf58 | c.537C>T p.T179= | Silent (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- DCHS1 | c.9549C>A p.I3183= | Silent (SNP) | VAF 58/185 reads (31%) | called by muse, mutect2, varscan2
- DDIAS | c.1347T>C p.N449= | Silent (SNP) | VAF 87/462 reads (19%) | called by muse, mutect2, varscan2
- DENND2B | c.978G>A p.P326= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- DENND3 | c.1794G>A p.R598= | Silent (SNP) | VAF 53/346 reads (15%) | called by muse, mutect2, varscan2
- DNAJC5 | c.189G>A p.A63= | Silent (SNP) | VAF 311/1023 reads (30%) | catalogued as rs746052000; ClinVar: likely benign; called by muse, mutect2, varscan2
- DSP | c.8217G>T p.P2739= | Silent (SNP) | VAF 58/422 reads (14%) | called by muse, mutect2, varscan2
- EPB41L3 | c.312C>T p.V104= | Silent (SNP) | VAF 57/529 reads (11%) | called by muse, varscan2
- ERICH6B | c.1932C>A p.P644= | Silent (SNP) | VAF 124/356 reads (35%) | called by mutect2, varscan2
- EXO1 | c.1107C>T p.S369= | Silent (SNP) | VAF 326/978 reads (33%) | called by muse, mutect2, varscan2
- FABP5 | c.51A>G p.K17= | Silent (SNP) | VAF 89/361 reads (25%) | called by muse, mutect2, varscan2
- FAM135B | c.3669C>A p.I1223= | Silent (SNP) | VAF 65/440 reads (15%) | catalogued as COSV99423912; called by muse, mutect2, varscan2
- FAM53B | c.357C>T p.F119= | Silent (SNP) | VAF 32/257 reads (12%) | catalogued as rs920792596; called by muse, mutect2, varscan2
- FAM71F1 | c.243C>T p.F81= | Silent (SNP) | VAF 43/255 reads (17%) | catalogued as COSV59374869; called by muse, varscan2
- FAT4 | c.8082A>C p.A2694= | Silent (SNP) | VAF 147/354 reads (42%) | called by muse, mutect2, varscan2
- FBN2 | c.4800C>A p.G1600= | Silent (SNP) | VAF 101/524 reads (19%) | catalogued as COSV99326498; called by muse, mutect2, varscan2
- FKBP10 | c.1296C>A p.A432= | Silent (SNP) | VAF 97/310 reads (31%) | called by muse, mutect2, varscan2
- FLRT2 | c.1521C>A p.T507= | Silent (SNP) | VAF 57/371 reads (15%) | called by muse, mutect2, varscan2
- FOXD4 | c.675C>T p.H225= | Silent (SNP) | VAF 159/460 reads (35%) | called by muse, mutect2, varscan2
- GAB4 | c.12G>A p.P4= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as rs1167981055, COSV101271915; called by muse, mutect2, varscan2
- GLI2 | c.2286C>A p.P762= (on ENST00000361492 / NM_001374353.1; = p.P779= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100082189; called by muse, mutect2, varscan2
- GMPPA | c.1095C>A p.P365= | Silent (SNP) | VAF 83/268 reads (31%) | called by muse, varscan2
- GUCA1C | c.63G>T p.V21= | Silent (SNP) | VAF 48/454 reads (11%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.768C>G p.S256= | Silent (SNP) | VAF 35/177 reads (20%) | catalogued as COSV99638287; called by muse, mutect2, varscan2
- HPN | c.780G>T p.L260= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV52882844; called by muse, mutect2, varscan2
- HR | c.1899G>T p.R633= | Silent (SNP) | VAF 48/190 reads (25%) | called by muse, mutect2, varscan2
- ICMT | c.132G>T p.L44= | Silent (SNP) | VAF 79/181 reads (44%) | called by muse, mutect2, varscan2
- IGHV3-16 | c.111G>T p.L37= | Silent (SNP) | VAF 101/485 reads (21%) | called by muse, mutect2, varscan2
- IGHV3-33 | c.78T>C p.S26= | Silent (SNP) | VAF 65/362 reads (18%) | called by muse, mutect2, varscan2
- IGKV3-11 | c.252C>A p.G84= | Silent (SNP) | VAF 174/1157 reads (15%) | called by muse, mutect2, varscan2
- IL18RAP | c.1035C>T p.N345= | Silent (SNP) | VAF 74/316 reads (23%) | catalogued as COSV51828003; called by muse, mutect2, varscan2
- IL21R | c.681A>T p.S227= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2
- ITGB2 | c.843C>A p.P281= | Silent (SNP) | VAF 43/233 reads (18%) | catalogued as CD109174; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1077C>A p.G359= (on ENST00000439118 / NM_001008949.3; = p.G367= on NM_178495.6) | Silent (SNP) | VAF 46/162 reads (28%) | called by muse, mutect2, varscan2
- KCNG3 | c.543G>C p.V181= | Silent (SNP) | VAF 21/98 reads (21%) | called by muse, mutect2, varscan2
- KCNMB2 | c.663G>A p.Q221= | Silent (SNP) | VAF 47/256 reads (18%) | catalogued as rs1367668075, COSV64202234; called by muse, mutect2, varscan2
- KLHL32 | c.1177C>T p.L393= | Silent (SNP) | VAF 62/418 reads (15%) | called by muse, mutect2, varscan2
- KLK5 | c.249G>A p.A83= | Silent (SNP) | VAF 117/465 reads (25%) | catalogued as rs774131295, COSV60450485; called by muse, mutect2, varscan2
- KRT31 | c.312G>A p.Q104= | Silent (SNP) | VAF 40/290 reads (14%) | called by muse, varscan2
- KRT84 | c.999C>A p.I333= | Silent (SNP) | VAF 70/926 reads (8%) | called by muse, mutect2
- LILRA1 | c.348G>T p.L116= | Silent (SNP) | VAF 23/214 reads (11%) | catalogued as rs1317627542; called by muse, varscan2
- LILRB2 | c.1413A>G p.L471= | Silent (SNP) | VAF 31/246 reads (13%) | catalogued as COSV58747136; called by muse, varscan2
- LMOD2 | c.312C>A p.I104= | Silent (SNP) | VAF 27/196 reads (14%) | catalogued as COSV71755589, COSV71755612; called by muse, mutect2, varscan2
- LMTK3 | c.2328G>T p.V776= | Silent (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- LMTK3 | c.690C>A p.G230= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV99541368; called by muse, mutect2
- LRRC14B | c.1308C>T p.Y436= | Silent (SNP) | VAF 668/1221 reads (55%) | called by muse, mutect2, varscan2
- LTBP2 | c.174C>T p.G58= | Silent (SNP) | VAF 88/535 reads (16%) | called by muse, mutect2, varscan2
- LYST | c.5601A>G p.K1867= | Silent (SNP) | VAF 28/242 reads (12%) | called by muse, varscan2
- MAN2B1 | c.741C>T p.P247= | Silent (SNP) | VAF 133/348 reads (38%) | called by muse, mutect2, varscan2
- MGAM | c.5094G>A p.K1698= | Silent (SNP) | VAF 60/598 reads (10%) | called by muse, mutect2
- MS4A10 | c.648A>G p.K216= | Silent (SNP) | VAF 34/333 reads (10%) | called by muse, mutect2, varscan2
- MUC16 | c.19212C>T p.T6404= | Silent (SNP) | VAF 63/180 reads (35%) | called by muse, mutect2, varscan2
- MUC5B | c.15112C>T p.L5038= | Silent (SNP) | VAF 49/348 reads (14%) | catalogued as rs1197147143; called by muse, mutect2, varscan2
- MXRA5 | c.3813C>A p.P1271= | Silent (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- MYCBP2 | c.3198G>T p.L1066= (on ENST00000357337; = p.L1104= on NM_015057.5) | Silent (SNP) | VAF 18/147 reads (12%) | catalogued as rs1163501153; called by muse, mutect2, varscan2
- MYH1 | c.5286C>A p.A1762= | Silent (SNP) | VAF 181/506 reads (36%) | called by muse, mutect2, varscan2
- MYH13 | c.5202G>T p.L1734= | Silent (SNP) | VAF 65/446 reads (15%) | called by muse, mutect2, varscan2
- MYH13 | c.4584G>A p.Q1528= | Silent (SNP) | VAF 128/375 reads (34%) | called by muse, mutect2, varscan2
- MYH13 | c.3996C>A p.A1332= | Silent (SNP) | VAF 118/307 reads (38%) | catalogued as rs1391278428; called by muse, mutect2, varscan2
- MYH13 | c.1713C>A p.A571= | Silent (SNP) | VAF 145/373 reads (39%) | called by muse, mutect2, varscan2
- MYH7 | c.2436G>T p.L812= | Silent (SNP) | VAF 58/462 reads (13%) | called by muse, mutect2, varscan2
- MYO18B | c.3933G>C p.V1311= | Silent (SNP) | VAF 42/783 reads (5%) | called by muse, mutect2
- MYO5C | c.4185G>T p.L1395= | Silent (SNP) | VAF 123/303 reads (41%) | called by muse, mutect2, varscan2
- NEMP1 | c.75T>A p.G25= | Silent (SNP) | VAF 178/376 reads (47%) | called by muse, mutect2, varscan2
- NFASC | c.1029C>A p.P343= (on ENST00000339876 / NM_001378329.1; = p.P354= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/495 reads (12%) | called by muse, mutect2, varscan2
- NIBAN2 | c.1635C>T p.V545= | Silent (SNP) | VAF 62/283 reads (22%) | called by muse, mutect2, varscan2
- NLRP6 | c.813G>T p.P271= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs781151412; called by mutect2, varscan2
- NOTCH4 | c.3885C>A p.P1295= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, varscan2
- NTM | c.261C>A p.R87= | Silent (SNP) | VAF 100/1092 reads (9%) | catalogued as rs200618752; called by muse, mutect2
- NUP205 | c.5097G>T p.G1699= | Silent (SNP) | VAF 46/205 reads (22%) | catalogued as rs367847599; called by muse, mutect2, varscan2
- NUP98 | c.5094A>G p.R1698= (on ENST00000359171 / NM_001365126.1; = p.R1681= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 75/211 reads (36%) | catalogued as rs781095304; called by muse, mutect2, varscan2
- OGFR | c.1383G>T p.V461= | Silent (SNP) | VAF 73/260 reads (28%) | called by muse, mutect2, varscan2
- OR10A4 | c.669C>A p.L223= | Silent (SNP) | VAF 104/388 reads (27%) | called by muse, mutect2, varscan2
- OR10G8 | c.174C>T p.Y58= | Silent (SNP) | VAF 95/787 reads (12%) | catalogued as COSV70909590; called by muse, mutect2, varscan2
- OR14I1 | c.694C>A p.R232= | Silent (SNP) | VAF 151/405 reads (37%) | catalogued as COSV61198982; called by muse, mutect2, varscan2
- OR2M5 | c.741G>T p.V247= | Silent (SNP) | VAF 105/880 reads (12%) | called by muse, mutect2, varscan2
- OR2T4 | c.78A>G p.K26= | Silent (SNP) | VAF 95/722 reads (13%) | called by muse, mutect2, varscan2
- OVCH1 | c.1350T>A p.I450= | Silent (SNP) | VAF 20/173 reads (12%) | catalogued as COSV100548156; called by muse, mutect2, varscan2
- PCDHA4 | c.1281G>T p.A427= | Silent (SNP) | VAF 346/783 reads (44%) | called by muse, mutect2, varscan2
- PCDHB7 | c.2259G>T p.L753= | Silent (SNP) | VAF 146/725 reads (20%) | called by muse, mutect2, varscan2
- PER2 | c.666C>T p.F222= | Silent (SNP) | VAF 84/826 reads (10%) | called by muse, varscan2
- PKLR | c.1120C>T p.L374= | Silent (SNP) | VAF 62/552 reads (11%) | called by muse, mutect2, varscan2
- PKNOX2 | c.135C>A p.I45= | Silent (SNP) | VAF 92/244 reads (38%) | catalogued as COSV100021370; called by muse, mutect2, varscan2
- POLR3D | c.540G>T p.L180= | Silent (SNP) | VAF 30/359 reads (8%) | called by muse, mutect2
- POTEJ | c.2763C>G p.P921= | Silent (SNP) | VAF 313/838 reads (37%) | called by muse, mutect2, varscan2
- PPP1R12A | c.1944G>T p.L648= | Silent (SNP) | VAF 62/259 reads (24%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.801G>A p.E267= | Silent (SNP) | VAF 62/1132 reads (5%) | called by muse, mutect2
- PRB1 | c.270C>A p.P90= | Silent (SNP) | VAF 118/445 reads (27%) | catalogued as COSV53706399; called by muse, mutect2, varscan2
- PROB1 | c.2769C>T p.P923= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs1326210973; called by muse, mutect2, varscan2
- PRRC2B | c.5295C>T p.V1765= | Silent (SNP) | VAF 27/578 reads (5%) | called by muse, mutect2
- PSG6 | c.1134C>T p.L378= | Silent (SNP) | VAF 114/723 reads (16%) | catalogued as rs1058781; called by muse, mutect2, varscan2
- PTPRD | c.702C>A p.V234= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as COSV100646329; called by muse, mutect2, varscan2
- RASGRF2 | c.3099G>A p.K1033= | Silent (SNP) | VAF 59/405 reads (15%) | catalogued as rs936074345; called by muse, mutect2, varscan2
- RIMS1 | c.5031C>A p.S1677= | Silent (SNP) | VAF 94/246 reads (38%) | catalogued as COSV53451002; called by muse, mutect2, varscan2
- RPS6KA4 | c.456G>A p.L152= | Silent (SNP) | VAF 27/192 reads (14%) | catalogued as COSV99589706; called by muse, mutect2, varscan2
- RUSC2 | c.2484C>T p.A828= | Silent (SNP) | VAF 104/300 reads (35%) | catalogued as rs1021278904; called by muse, mutect2, varscan2
- SAP30L | c.303G>A p.E101= | Silent (SNP) | VAF 111/271 reads (41%) | called by muse, mutect2, varscan2
- SCARF2 | c.1785G>A p.L595= | Silent (SNP) | VAF 17/301 reads (6%) | catalogued as rs1206542674; called by muse, mutect2
- SEMA4F | c.84G>C p.L28= | Silent (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- SERPINA5 | c.1220G>A p.*407= | Silent (SNP) | VAF 22/123 reads (18%) | called by muse, varscan2
- SERPINA6 | c.111G>A p.R37= | Silent (SNP) | VAF 61/415 reads (15%) | catalogued as rs773851571; called by muse, mutect2, varscan2
- SHANK1 | c.1350G>C p.V450= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- SIDT2 | c.1978C>T p.L660= | Silent (SNP) | VAF 54/306 reads (18%) | catalogued as rs772605239; called by muse, mutect2, varscan2
- SIPA1L1 | c.5247G>A p.K1749= | Silent (SNP) | VAF 45/330 reads (14%) | called by muse, mutect2, varscan2
- SIX5 | c.939G>T p.A313= | Silent (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
- SLC12A3 | c.1599C>T p.S533= | Silent (SNP) | VAF 107/825 reads (13%) | called by muse, mutect2, varscan2
- SLC15A4 | c.1140C>T p.L380= | Silent (SNP) | VAF 27/242 reads (11%) | called by muse, mutect2, varscan2
- SLC16A2 | c.1104C>T p.G368= | Silent (SNP) | VAF 98/345 reads (28%) | called by muse, mutect2, varscan2
- SLC1A6 | c.1032G>T p.L344= | Silent (SNP) | VAF 75/228 reads (33%) | called by muse, mutect2, varscan2
- SLC22A6 | c.1680G>A p.K560= | Silent (SNP) | VAF 61/204 reads (30%) | called by muse, mutect2, varscan2
- SLC52A3 | c.165C>T p.P55= | Silent (SNP) | VAF 98/305 reads (32%) | catalogued as rs1375021792; called by muse, mutect2, varscan2
- SNX19 | c.2736G>A p.Q912= | Silent (SNP) | VAF 32/239 reads (13%) | catalogued as rs1398856590; called by muse, varscan2
- ST3GAL5 | c.666T>A p.V222= (on ENST00000377332; = p.V262= on NM_003896.4) | Silent (SNP) | VAF 137/553 reads (25%) | called by muse, mutect2, varscan2
- SYN3 | c.471C>T p.F157= | Silent (SNP) | VAF 58/236 reads (25%) | catalogued as rs1335932970; called by muse, varscan2
- TEP1 | c.4677G>T p.S1559= | Silent (SNP) | VAF 69/395 reads (17%) | called by muse, mutect2, varscan2
- TEX13C | c.1620G>T p.G540= | Silent (SNP) | VAF 254/676 reads (38%) | called by muse, mutect2, varscan2
124 further variants in this file (0 protein-altering or splice-affecting, 21 silent, 103 other) are not listed here.
